Somatic mutation profile of tumor specimen C3L-06299-02 (aliquot CPT0362960009) from CPTAC case C3L-06299, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 71.9 years (26,247 days).
Specimen C3L-06299-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 801c5397-e3dd-4297-a957-57f1c1d6c311.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06299-32 (Blood Derived Normal), aliquot CPT0363050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2da3c836-0542-49c6-9dec-857d49d2a22b

The open-access MAF lists 1,118 somatic variants for this specimen: 701 protein-altering or splice-affecting, 382 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 638, Silent 382, Nonsense Mutation 41, Intron 16, Splice Region 9, Splice Site 8, 5'Flank 6, RNA 4, Frame Shift Del 4, 3'UTR 4, 5'UTR 4, 3'Flank 1.

Variants (750 of 1,118; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 213/230 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL4A5 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 123/133 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569494378, CM159372; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN9A | c.2424G>A p.W808* (on ENST00000303354; = p.W797* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 115/400 reads (29%) | catalogued as rs769971743; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 92/254 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210571370, COSV99229312; called by muse, mutect2, varscan2
- ABLIM3 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 190/340 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs757248481; called by muse, mutect2, varscan2
- ABLIM3 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as rs759025870, COSV58643879; called by muse, mutect2, varscan2
- ACP4 | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 171/207 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as rs950862315; called by muse, mutect2, varscan2
- ADAM10 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 116/305 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs200668065, COSV53049366; called by muse, mutect2, varscan2
- ADAM18 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 115/295 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs752996370, COSV55844420, COSV55851975; called by muse, mutect2, varscan2
- ADAMTS7 | c.103C>G p.R35G | Missense Mutation (SNP) | VAF 145/333 reads (44%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.007); catalogued as COSV66306178; called by muse, mutect2, varscan2
- ADCY4 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 160/250 reads (64%) | SIFT tolerated (0.4); PolyPhen benign (0.059); catalogued as rs79766112; called by muse, mutect2, varscan2
- ADCY9 | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 291/614 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); catalogued as rs750993435; called by muse, mutect2, varscan2
- ADH1A | c.570C>T p.V190= | Splice Region (SNP) | VAF 81/260 reads (31%) | catalogued as rs771570339; called by muse, mutect2, varscan2
- ADSS1 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as COSV100272545; called by muse, mutect2, varscan2
- AGER | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 350/387 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762118793; called by muse, mutect2, varscan2
- AGL | c.4459C>T p.R1487* | Nonsense Mutation (SNP) | VAF 133/143 reads (93%) | catalogued as rs12118058; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.7627C>T p.Q2543* | Nonsense Mutation (SNP) | VAF 178/662 reads (27%) | catalogued as COSV60909482; called by muse, mutect2
- AIFM2 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 185/290 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775593494; called by muse, mutect2, varscan2
- AJM1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 248/404 reads (61%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs753594723; called by muse, varscan2
- AMER3 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 274/434 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as rs1365927046; called by muse, mutect2, varscan2
- ANK1 | c.4106G>A p.G1369E | Missense Mutation (SNP) | VAF 136/327 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.172); catalogued as rs1029147697; called by muse, mutect2, varscan2
- ANO3 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.357); catalogued as rs758733002, COSV56785193; called by muse, mutect2, varscan2
- ANO7 | c.1444G>A p.G482S (on ENST00000274979; = p.G428S on NM_001370694.2) | Missense Mutation (SNP) | VAF 144/480 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1251719865; called by muse, mutect2, varscan2
- APOA4 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 149/431 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs771829056, COSV63361282; called by muse, mutect2, varscan2
- APOB | c.10899G>A p.W3633* | Nonsense Mutation (SNP) | VAF 127/371 reads (34%) | catalogued as COSV51938071; called by muse, mutect2, varscan2
- ARAP3 | c.2995C>T p.R999C | Missense Mutation (SNP) | VAF 155/247 reads (63%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.825); catalogued as rs1464135643, COSV53353646; called by muse, mutect2, varscan2
- ARHGAP19 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1407541980, COSV100363078; called by muse, mutect2
- ARHGAP28 | c.347G>A p.W116* | Nonsense Mutation (SNP) | VAF 82/256 reads (32%) | catalogued as rs1395369749, COSV99148256; called by muse, mutect2, varscan2
- ARHGEF5 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 415/466 reads (89%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs1275222272; called by muse, mutect2, varscan2
- ARSF | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 225/237 reads (95%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV100839471; called by muse, mutect2, varscan2
- ARSH | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 159/175 reads (91%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs762843427; called by muse, mutect2, varscan2
- ASXL3 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 98/321 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV52478934; called by muse, mutect2, varscan2
- ASXL3 | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 117/375 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.02); catalogued as COSV52464752; called by muse, mutect2, varscan2
- ASXL3 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 204/338 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); catalogued as rs749484741, COSV52457610; called by muse, mutect2, varscan2
- ATP13A1 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 56/1416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52284728; called by muse, mutect2
- ATP1A3 | c.1253C>T p.S418L (on ENST00000545399 / NM_001256214.2; = p.S405L on NM_152296.5) | Missense Mutation (SNP) | VAF 175/1184 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs368489500; called by muse, mutect2, varscan2
- B3GNT6 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 158/514 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV62828218; called by muse, mutect2, varscan2
- BDKRB1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 297/468 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV99387983; called by muse, mutect2, varscan2
- BEST3 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 253/292 reads (87%) | SIFT tolerated (0.3); PolyPhen benign (0.108); catalogued as rs372783693; called by muse, mutect2, varscan2
- BMS1 | c.2212C>T p.L738F | Missense Mutation (SNP) | VAF 95/316 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.091); catalogued as COSV100996688; called by muse, mutect2, varscan2
- BTBD8 | c.5288C>T p.S1763F (on ENST00000636805 / NM_001376131.1; = p.S1250F on NM_015237.4) | Missense Mutation (SNP) | VAF 197/218 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1340890089; called by muse, mutect2, varscan2
- C16orf54 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 316/700 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as rs1326706780; called by muse, mutect2, varscan2
- C3orf20 | c.2671G>A p.D891N | Missense Mutation (SNP) | VAF 156/179 reads (87%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs764426748; called by muse, mutect2, varscan2
- C8orf34 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 101/251 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs771361055, COSV57397940; called by muse, mutect2, varscan2
- C9 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752732847, COSV54676755, COSV54677490, COSV99073166; called by muse, mutect2, varscan2
- CACNA2D4 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 231/433 reads (53%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.953); catalogued as rs746971613, COSV54949632; called by muse, mutect2, varscan2
- CARMIL3 | c.2417C>T p.P806L | Missense Mutation (SNP) | VAF 207/356 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57728190; called by muse, mutect2, varscan2
- CASR | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 202/228 reads (89%) | SIFT tolerated (0.55); PolyPhen benign (0.234); catalogued as rs121909262, CM950198, COSV56133823; called by muse, mutect2, varscan2
- CCDC105 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 154/172 reads (90%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as COSV52963797; called by muse, mutect2, varscan2
- CCDC136 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 177/187 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs267601275, COSV99922969; called by muse, mutect2, varscan2
- CCDC175 | c.1842+1G>A p.X614_splice | Splice Site (SNP) | VAF 39/119 reads (33%) | catalogued as rs965559240; called by muse, mutect2, varscan2
- CCDC185 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 297/457 reads (65%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.848); catalogued as COSV64821474; called by muse, mutect2, varscan2
- CCDC38 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 228/242 reads (94%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100717257; called by muse, mutect2, varscan2
- CCDC88C | c.5593G>A p.G1865R | Missense Mutation (SNP) | VAF 346/514 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs1475867401; called by muse, mutect2, varscan2
- CD163L1 | c.2720C>T p.S907F | Missense Mutation (SNP) | VAF 230/395 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58019648; called by muse, mutect2, varscan2
- CD163L1 | c.2530C>T p.L844F | Missense Mutation (SNP) | VAF 277/510 reads (54%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as COSV58021170; called by muse, mutect2, varscan2
- CD300LG | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 160/250 reads (64%) | SIFT tolerated (0.62); PolyPhen benign (0.039); catalogued as COSV53225784; called by muse, mutect2, varscan2
- CD9 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 201/403 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); catalogued as COSV50530981; called by muse, mutect2, varscan2
- CDH18 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 116/363 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868656497, COSV56901982, COSV56932375, COSV56960090; called by muse, mutect2, varscan2
- CDH9 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 177/277 reads (64%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.491); catalogued as rs867901234, COSV50264302, COSV50324297; called by muse, mutect2, varscan2
- CFH | c.3512G>A p.R1171Q | Missense Mutation (SNP) | VAF 104/184 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV66406620; called by muse, varscan2
- CFH | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 101/336 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as CM060895, CM070672, COSV66407688; called by muse, varscan2
- CFTR | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 230/247 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM962450; called by muse, mutect2, varscan2
- CHGB | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 248/519 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66761049; called by muse, mutect2, varscan2
- CHL1 | c.2224G>A p.G742R (on ENST00000397491 / NM_001253387.1; = p.G758R on NM_006614.4) | Missense Mutation (SNP) | VAF 179/194 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56594052; called by muse, mutect2, varscan2
- CLEC4C | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 117/224 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV63582651, COSV63583304; called by muse, mutect2, varscan2
- CLN6 | c.489C>T p.I163= | Splice Region (SNP) | VAF 179/385 reads (46%) | catalogued as rs748682605, COSV51116585; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNGA3 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 267/407 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs370911601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL14A1 | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 116/242 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs747111651; called by muse, mutect2, varscan2
- COL21A1 | c.1993G>A p.G665R | Missense Mutation (SNP) | VAF 180/189 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55169851, COSV99779105; called by muse, mutect2, varscan2
- COL4A3 | c.4082G>A p.G1361E | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474483369; called by muse, mutect2, varscan2
- COL5A2 | c.2519G>A p.G840E | Missense Mutation (SNP) | VAF 100/196 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66409657; called by muse, mutect2, varscan2
- COL6A3 | c.6139G>C p.G2047R | Missense Mutation (SNP) | VAF 109/316 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1312505; called by muse, mutect2, varscan2
- CPNE4 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 153/161 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1353586941, COSV70202451; called by muse, mutect2, varscan2
- CR2 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 84/296 reads (28%) | catalogued as rs747713309; called by muse, mutect2, varscan2
- CSMD1 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 94/190 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68165274, COSV68210092; called by muse, mutect2, varscan2
- CSMD3 | c.9958C>T p.P3320S (on ENST00000297405 / NM_001363185.1; = p.P3151S on NM_052900.3) | Missense Mutation (SNP) | VAF 261/525 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV52271134; called by muse, mutect2, varscan2
- CTNNA2 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 103/298 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV63573698; called by muse, varscan2
- CTNNA2 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 102/299 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63568165; called by muse, varscan2
- CTNND2 | c.2993G>A p.G998E | Missense Mutation (SNP) | VAF 122/201 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58862221, COSV58874910; called by muse, mutect2, varscan2
- CTNND2 | c.2992G>A p.G998R | Missense Mutation (SNP) | VAF 123/203 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58885716; called by muse, mutect2, varscan2
- CTSE | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 163/230 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1553278677; called by muse, mutect2, varscan2
- CTSG | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 129/386 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as rs1442527104; called by muse, mutect2, varscan2
- CYLC2 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 145/221 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66336729, COSV66339490; called by muse, mutect2, varscan2
- CYRIA | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 99/318 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV62864775; called by muse, mutect2, varscan2
- DCST2 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 247/366 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs748120484; called by muse, mutect2, varscan2
- DEFA4 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 224/477 reads (47%) | catalogued as COSV52404792; called by muse, mutect2, varscan2
- DENND5A | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 93/173 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs758183835, COSV60233221, COSV60234125; called by muse, mutect2, varscan2
- DGKB | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs536197059, COSV51761131; called by muse, mutect2, varscan2
- DHX57 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV54883892; called by muse, mutect2, varscan2
- DLEC1 | c.5213G>A p.R1738Q | Missense Mutation (SNP) | VAF 134/1190 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as rs887127240, COSV57170137; called by muse, varscan2
- DNAH17 | c.10823G>A p.G3608E | Missense Mutation (SNP) | VAF 208/308 reads (68%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs766260760; called by muse, mutect2, varscan2
- DNAH5 | c.7916G>A p.R2639Q | Missense Mutation (SNP) | VAF 132/215 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140968268, COSV54202500; called by muse, mutect2, varscan2
- DNAH5 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 117/190 reads (62%) | catalogued as rs771463510, CM091929; called by muse, mutect2, varscan2
- DNAH6 | c.7153G>A p.A2385T | Missense Mutation (SNP) | VAF 98/156 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs768716579; called by muse, mutect2, varscan2
- DNAH7 | c.8282C>T p.P2761L | Missense Mutation (SNP) | VAF 80/263 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1350992578; called by muse, mutect2, varscan2
- DNAH7 | c.2293C>T p.P765S | Missense Mutation (SNP) | VAF 83/316 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56780713; called by muse, mutect2, varscan2
- DNAH9 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 78/287 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.196); catalogued as rs1440231286, COSV52336233; called by muse, mutect2, varscan2
- DNAH9 | c.4864C>T p.P1622S | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52351351; called by muse, mutect2, varscan2
- DSCAM | c.2974C>T p.H992Y | Missense Mutation (SNP) | VAF 200/441 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV68033997; called by muse, mutect2, varscan2
- DSG1 | c.1940G>A p.G647E | Missense Mutation (SNP) | VAF 175/289 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs768142206; called by muse, mutect2, varscan2
- EFR3A | c.2074C>T p.R692* | Nonsense Mutation (SNP) | VAF 87/178 reads (49%) | catalogued as rs770587283, COSV54453226; called by muse, mutect2, varscan2
- ELF1 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs780405638; called by muse, varscan2
- ELMO1 | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60300577; called by muse, mutect2, varscan2
- ELMOD1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 130/223 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99760548; called by muse, mutect2, varscan2
- ELP3 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 240/505 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs367635310; called by muse, mutect2, varscan2
- EPO | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 206/220 reads (94%) | SIFT tolerated (0.12); PolyPhen benign (0.262); catalogued as rs746545386; called by muse, mutect2, varscan2
- ERC2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 201/217 reads (93%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs866429245, COSV55642982; called by muse, mutect2, varscan2
- ERF | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 154/2079 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as rs758497035; called by muse, mutect2
- ETV1 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 151/252 reads (60%) | SIFT tolerated (0.5); PolyPhen benign (0.07); catalogued as COSV54151214; called by muse, mutect2, varscan2
- EVI2B | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 211/368 reads (57%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as COSV58363355; called by muse, mutect2, varscan2
- EVPL | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 133/441 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs747537304, COSV56907331; called by muse, mutect2, varscan2
- FADS6 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 171/297 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479490673; called by muse, mutect2, varscan2
- FAM184B | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 148/402 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.833); catalogued as rs368984354; called by muse, mutect2, varscan2
- FAM189B | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 229/362 reads (63%) | SIFT tolerated (0.71); PolyPhen benign (0.107); catalogued as rs376213640; called by muse, mutect2, varscan2
- FAM3A | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 122/145 reads (84%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs935454242; called by muse, mutect2, varscan2
- FBLN5 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99969451; called by muse, mutect2, varscan2
- FBN1 | c.2098C>T p.P700S | Missense Mutation (SNP) | VAF 153/357 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745694291; called by muse, mutect2, varscan2
- FBN2 | c.3793G>A p.E1265K | Missense Mutation (SNP) | VAF 178/289 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs776031352, CM158361, COSV52514792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO15 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 112/427 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs146975565; called by muse, mutect2, varscan2
- FBXO47 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 170/280 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs1048041203; called by muse, mutect2, varscan2
- FGF5 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 70/121 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100427842; called by muse, mutect2, varscan2
- FMN2 | c.5099G>A p.G1700E | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as COSV60420981; called by muse, mutect2, varscan2
- FMO1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 102/170 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV61444890; called by muse, mutect2
- FRMD8 | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 245/401 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV58213152; called by muse, mutect2, varscan2
- FRMPD2 | c.2045C>A p.S682* | Nonsense Mutation (SNP) | VAF 221/392 reads (56%) | catalogued as COSV100563850; called by muse, mutect2, varscan2
- GABPB1 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 165/395 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs139444439, COSV55016460; called by muse, mutect2, varscan2
- GABRG1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV54957270; called by muse, mutect2, varscan2
- GATAD2A | c.1739C>T p.T580I | Missense Mutation (SNP) | VAF 198/1949 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs774088762; called by muse, mutect2
- GCSAML | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 107/356 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV63578549; called by muse, mutect2, varscan2
- GEM | c.408+1G>A p.X136_splice | Splice Site (SNP) | VAF 144/280 reads (51%) | catalogued as rs201196388; called by muse, mutect2, varscan2
- GLRB | c.417G>A p.W139* | Nonsense Mutation (SNP) | VAF 169/301 reads (56%) | catalogued as COSV52415665; called by muse, mutect2, varscan2
- GMEB2 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 292/685 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs752805008, COSV56607678; called by muse, mutect2, varscan2
- GNB1L | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 226/505 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs757925867; called by muse, mutect2, varscan2
- GOLGA3 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 421/441 reads (95%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.001); catalogued as rs372143485, COSV99212837; called by muse, mutect2, varscan2
- GOLGA8H | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 206/494 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as rs1256741163; called by muse, mutect2, varscan2
- GPN1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 101/327 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs373008981, COSV104391862; called by muse, mutect2, varscan2
- GPR65 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 103/303 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV50862801; called by muse, mutect2, varscan2
- GRIA1 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 168/252 reads (67%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.434); catalogued as COSV99600734; called by muse, mutect2, varscan2
- GRIA3 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 96/113 reads (85%) | SIFT tolerated (0.25); PolyPhen benign (0.195); catalogued as rs368568228, CM074895, COSV52075549; called by muse, mutect2, varscan2
- GRIN2A | c.3617G>A p.R1206Q | Missense Mutation (SNP) | VAF 291/577 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.986); catalogued as rs145861983; called by muse, mutect2, varscan2
- GRN | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 88/305 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs529849967, CM099945, COSV50006207; called by muse, mutect2
- GUCY1A2 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 204/331 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56492186; called by muse, mutect2, varscan2
- GYPC | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 206/343 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0.274); catalogued as rs1451670905, COSV52145679; called by muse, mutect2
- HECTD4 | c.3836C>T p.P1279L | Missense Mutation (SNP) | VAF 249/265 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61180190; called by muse, mutect2, varscan2
- HECW1 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 163/440 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773660516; called by muse, mutect2, varscan2
- HGFAC | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 102/327 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs764843323; called by muse, mutect2, varscan2
- HID1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 196/335 reads (59%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.73); catalogued as rs370760336; called by muse, mutect2, varscan2
- HMGXB3 | c.2366C>T p.S789F (on ENST00000613459; = p.S543F on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 161/259 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as rs1331449930; called by muse, mutect2, varscan2
- HYDIN | c.10427G>A p.R3476Q | Missense Mutation (SNP) | VAF 180/403 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.267); catalogued as rs553627913; called by muse, mutect2, varscan2
- IFNAR2 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 122/256 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.783); catalogued as rs768519080, COSV59749618; called by muse, mutect2, varscan2
- IGKV1D-43 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 214/346 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs576853442; called by muse, mutect2, varscan2
- IGSF10 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 231/251 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56791069; called by muse, mutect2, varscan2
- IGSF9B | c.2668C>T p.R890C | Missense Mutation (SNP) | VAF 292/470 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs374602069; called by muse, varscan2
- IL22RA1 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 262/277 reads (95%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs768825346, COSV54630606; called by muse, mutect2, varscan2
- IMPG2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 120/128 reads (94%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.756); catalogued as COSV51984498; called by muse, mutect2, varscan2
- INTS1 | c.6281C>T p.S2094L | Missense Mutation (SNP) | VAF 281/442 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs1018923942; called by muse, mutect2, varscan2
- ITPR2 | c.2854C>T p.P952S | Missense Mutation (SNP) | VAF 221/616 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs373812900; called by muse, mutect2, varscan2
- JAKMIP1 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 359/577 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs557009257, COSV51539456; called by muse, mutect2, varscan2
- JMJD1C | c.3250G>A p.V1084M | Missense Mutation (SNP) | VAF 157/275 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.138); catalogued as rs200952020; called by muse, mutect2, varscan2
- KCNB2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 179/414 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs756118503, COSV73049946; called by muse, mutect2, varscan2
- KCNH1 | c.2476G>A p.G826R (on ENST00000271751 / NM_172362.3; = p.G799R on NM_002238.4) | Missense Mutation (SNP) | VAF 145/492 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs541664168, COSV55068668; called by muse, mutect2, varscan2
- KCNH5 | c.2698C>T p.P900S | Missense Mutation (SNP) | VAF 117/389 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.021); catalogued as COSV104402632; called by muse, mutect2, varscan2
- KCNH5 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100527372; called by muse, mutect2, varscan2
- KCNH7 | c.2924G>A p.G975E | Missense Mutation (SNP) | VAF 173/289 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV59786691; called by muse, mutect2, varscan2
- KCNK9 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 181/421 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57278639; called by muse, mutect2, varscan2
- KCNQ3 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 192/455 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs866640701; called by muse, mutect2, varscan2
- KIAA0825 | c.2285C>T p.S762F | Missense Mutation (SNP) | VAF 118/196 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV56948166; called by muse, mutect2, varscan2
- KIR3DL3 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 275/1111 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs1385416819; called by muse, mutect2, varscan2
- KMT2D | c.15907C>T p.R5303C | Missense Mutation (SNP) | VAF 249/267 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs980258889; called by muse, mutect2, varscan2
- KRBA1 | c.2569C>T p.L857F | Missense Mutation (SNP) | VAF 477/502 reads (95%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1027450744; called by muse, mutect2, varscan2
- KRT12 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 102/340 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778543318, COSV52430109; called by muse, mutect2, varscan2
- KRTAP10-4 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 163/947 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100553966; called by muse, mutect2, varscan2
- LARGE1 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 186/413 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.053); catalogued as rs771499820, COSV61658259; called by muse, mutect2, varscan2
- LAT | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 252/536 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57953567; called by muse, mutect2, varscan2
- LCN2 | c.276-1G>A p.X92_splice | Splice Site (SNP) | VAF 87/260 reads (33%) | catalogued as COSV52981554; called by muse, mutect2, varscan2
- LELP1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 313/514 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); catalogued as rs761668608, COSV64202571; called by muse, mutect2, varscan2
- LEPR | c.3194G>A p.G1065E | Missense Mutation (SNP) | VAF 142/152 reads (93%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV62745991; called by muse, mutect2, varscan2
- LLGL2 | c.2347G>A p.D783N | Missense Mutation (SNP) | VAF 235/387 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769989122, COSV51352625; called by muse, mutect2, varscan2
- LPA | c.2503C>T p.R835* | Nonsense Mutation (SNP) | VAF 144/400 reads (36%) | catalogued as rs746733669, COSV100305985; called by muse, varscan2
- LRP1B | c.12415C>T p.R4139* | Nonsense Mutation (SNP) | VAF 41/164 reads (25%) | catalogued as rs1263766326, COSV67232067, COSV67287432; called by muse, mutect2, varscan2
- LRRC37B | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 109/410 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.644); catalogued as rs780110966; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 261/287 reads (91%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as rs762713561; called by muse, mutect2, varscan2
- MALRD1 | c.4899T>G p.N1633K | Missense Mutation (SNP) | VAF 95/296 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV66004623; called by muse, mutect2, varscan2
- MAMDC2 | c.2001G>A p.M667I | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1310837959; called by muse, mutect2, varscan2
- MAN1A1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 68/77 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1213082733, COSV63781141, COSV63783109; called by muse, mutect2, varscan2
- MAP1A | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 290/553 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV55811641; called by muse, mutect2, varscan2
- MASP1 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 240/273 reads (88%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1335869764; called by muse, mutect2, varscan2
- MAST3 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 168/371 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1376711309, COSV99444062; called by muse, mutect2, varscan2
- MAST4 | c.5753C>T p.P1918L (on ENST00000403625 / NM_001164664.2; = p.P1729L on NM_015183.3) | Missense Mutation (SNP) | VAF 117/396 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs1385190285; called by muse, mutect2, varscan2
- MED14 | c.4121C>T p.S1374L | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs749256725, COSV100247578; called by muse, mutect2, varscan2
- MEIOC | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as rs866802792, COSV63439783; called by muse, mutect2, varscan2
- MEIS2 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 252/556 reads (45%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); catalogued as COSV54930885; called by muse, mutect2, varscan2
- MGAM | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 248/263 reads (94%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs782373494, COSV72074044, COSV72074183; called by muse, mutect2, varscan2
- MNDA | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 269/404 reads (67%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.638); catalogued as rs758460453, COSV63741371, COSV63741658; called by muse, mutect2, varscan2
- MTFMT | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 141/301 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767478510, COSV54977110, COSV54978561; called by muse, mutect2, varscan2
- MTMR12 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 41/147 reads (28%) | catalogued as COSV99374030; called by muse, mutect2, varscan2
- MTUS1 | c.2578C>T p.P860S | Missense Mutation (SNP) | VAF 143/303 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as rs749543033, COSV100029978; called by muse, mutect2, varscan2
- MUC12 | c.8644C>T p.R2882C (on ENST00000379442; = p.R2739C on NM_001164462.1) | Missense Mutation (SNP) | VAF 414/3516 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV65213081; called by muse, varscan2
- MUC16 | c.35583G>A p.M11861I | Missense Mutation (SNP) | VAF 228/242 reads (94%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs754483495, COSV67456054; called by muse, mutect2, varscan2
- MUC16 | c.20389G>A p.E6797K | Missense Mutation (SNP) | VAF 184/212 reads (87%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs1035643146; called by muse, mutect2, varscan2
- MUC16 | c.15355C>T p.P5119S | Missense Mutation (SNP) | VAF 166/178 reads (93%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV67449282; called by muse, mutect2, varscan2
- MYH2 | c.4633G>A p.E1545K | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as COSV99820742; called by muse, mutect2, varscan2
- MYH3 | c.3908C>T p.S1303F | Missense Mutation (SNP) | VAF 135/232 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs755407450; called by muse, mutect2, varscan2
- MYH3 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 152/254 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1160002369, COSV56864439; called by muse, mutect2, varscan2
- MYH7 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 238/399 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62518376; called by muse, mutect2, varscan2
- MYO18B | c.7591C>T p.P2531S | Missense Mutation (SNP) | VAF 191/426 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV59149632; called by muse, mutect2, varscan2
- MYO7B | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 197/325 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748548348; called by muse, mutect2, varscan2
- NAV3 | c.7033C>T p.P2345S (on ENST00000397909 / NM_001024383.2; = p.P2323S on NM_014903.6) | Missense Mutation (SNP) | VAF 152/160 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57061433; called by muse, mutect2, varscan2
- NDST4 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 164/265 reads (62%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.026); catalogued as rs142128243; called by muse, mutect2, varscan2
- NEK5 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62881573; called by muse, mutect2, varscan2
- NEURL4 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 95/293 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs773030979, COSV59761697; called by muse, mutect2, varscan2
- NIPA1 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 262/537 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs865888186, COSV61679925; called by muse, mutect2, varscan2
- NLRC4 | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 105/360 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61591978, COSV61595052; called by muse, mutect2, varscan2
- NLRP3 | c.1994C>T p.S665F | Missense Mutation (SNP) | VAF 89/327 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV60221512; called by muse, mutect2, varscan2
- NLRP8 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 139/461 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV52584772; called by muse, mutect2, varscan2
- NMD3 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 143/154 reads (93%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1377156562, COSV63618878; called by muse, mutect2, varscan2
- NPAS3 | c.1369G>A p.E457K (on ENST00000356141 / NM_001164749.2; = p.E425K on NM_022123.3) | Missense Mutation (SNP) | VAF 193/308 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs773753615, COSV60852060; called by muse, mutect2, varscan2
- NPIPB15 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 135/886 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.934); catalogued as rs1413888777; called by muse, mutect2, varscan2
- NUP205 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 182/200 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs112867264; called by muse, mutect2, varscan2
- NUP210L | c.2870G>A p.G957E | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55145573; called by muse, mutect2, varscan2
- NYAP2 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 291/506 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs186778268, COSV56003333, COSV99797737; called by muse, mutect2, varscan2
- OR10J1 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 77/297 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs773507434; called by muse, mutect2, varscan2
- OR13C5 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 157/271 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV66164105; called by muse, mutect2, varscan2
- OR13C8 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 201/283 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV58612511; called by muse, mutect2, varscan2
- OR1L1 | c.931C>T p.Q311* (on ENST00000373686; = p.Q261* on NM_001005236.3) | Nonsense Mutation (SNP) | VAF 233/382 reads (61%) | catalogued as COSV100542178; called by muse, mutect2, varscan2
- OR2A5 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 369/395 reads (93%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV68738894; called by muse, mutect2, varscan2
- OR2B11 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 125/480 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs777601323, COSV59509567; called by muse, mutect2
- OR2L2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV63553622; called by muse, mutect2, varscan2
- OR2T12 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 136/492 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV58779969; called by muse, varscan2
- OR4K5 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 112/370 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs563493636, COSV60003219; called by muse, mutect2, varscan2
- OR4N2 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 85/516 reads (16%) | catalogued as COSV60051118; called by muse, mutect2, varscan2
- OR4Q3 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 138/357 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV59177523; called by muse, mutect2, varscan2
- OR51B2 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 101/296 reads (34%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.973); catalogued as rs768082370; called by muse, mutect2, varscan2
- OR51L1 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 108/321 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100386511, COSV58625238; called by muse, mutect2, varscan2
- OR51S1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 106/404 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV59059718; called by muse, mutect2, varscan2
- OR5B17 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 201/292 reads (69%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.919); catalogued as COSV62160298, COSV62160338; called by muse, mutect2, varscan2
- OR5L2 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 190/328 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as rs1175845172, COSV65723909, COSV65724444; called by muse, varscan2
- OR6K6 | c.575C>T p.S192F (on ENST00000368144; = p.S168F on NM_001005184.1) | Missense Mutation (SNP) | VAF 260/414 reads (63%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.926); catalogued as COSV63744422; called by muse, mutect2, varscan2
- OR8D2 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 116/314 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1413853305; called by muse, mutect2, varscan2
- OR8D2 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 216/357 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1020678863, COSV62488112; called by muse, mutect2, varscan2
- OSBPL5 | c.1456C>T p.H486Y | Missense Mutation (SNP) | VAF 247/391 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99720296; called by muse, mutect2, varscan2
- P4HA3 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs147203342; called by muse, mutect2, varscan2
- PABPC4L | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 75/256 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as rs1466240221, COSV69930213; called by muse, mutect2, varscan2
- PAX5 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 234/256 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV100814270; called by muse, mutect2, varscan2
- PCDH18 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 117/400 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61268410, COSV61268565; called by muse, mutect2, varscan2
- PCDH19 | c.2797G>A p.D933N (on ENST00000373034 / NM_001184880.2; = p.D885N on NM_020766.3) | Missense Mutation (SNP) | VAF 118/133 reads (89%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs1462304045; called by muse, mutect2, varscan2
- PCDHB6 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 189/625 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV50706785; called by muse, mutect2, varscan2
- PCDHGA6 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 77/338 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1200666906, COSV53909508; called by muse, mutect2, varscan2
- PCDHGA6 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 76/341 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV54044354; called by muse, mutect2, varscan2
- PCDHGB4 | c.1697G>A p.G566D | Missense Mutation (SNP) | VAF 154/481 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.089); catalogued as rs375244906; called by muse, mutect2, varscan2
- PCLO | c.15281C>T p.S5094F | Missense Mutation (SNP) | VAF 178/189 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1464996435; called by muse, mutect2, varscan2
- PCLO | c.4285G>A p.D1429N | Missense Mutation (SNP) | VAF 312/326 reads (96%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs752862200, COSV61643890; called by muse, mutect2, varscan2
- PDE6B | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 94/371 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs866891056; called by muse, mutect2, varscan2
- PDK1 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 149/268 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56376378; called by muse, mutect2, varscan2
- PDYN | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 241/536 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771766231, COSV54102194; called by muse, mutect2, varscan2
- PGLYRP3 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 168/246 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs144049973, COSV99319620; called by muse, mutect2, varscan2
- PHF3 | c.5326C>T p.P1776S | Missense Mutation (SNP) | VAF 221/235 reads (94%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1445822408, COSV50313855; called by muse, mutect2, varscan2
- PIEZO2 | c.2510G>A p.G837E | Missense Mutation (SNP) | VAF 91/308 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV57436716; called by muse, mutect2, varscan2
- PIEZO2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.187); catalogued as rs1341628000, COSV57427771; called by muse, mutect2, varscan2
- PIK3C2G | c.4195G>A p.G1399S (on ENST00000676171; = p.G1358S on NM_004570.5) | Missense Mutation (SNP) | VAF 106/288 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56825051; called by muse, mutect2, varscan2
- PKD1 | c.4768C>T p.P1590S | Missense Mutation (SNP) | VAF 241/533 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.852); catalogued as rs1344522787; called by muse, mutect2, varscan2
- PKHD1L1 | c.2767C>T p.H923Y | Missense Mutation (SNP) | VAF 188/414 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs958715836, COSV65740825; called by muse, mutect2, varscan2
- PLA2R1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 144/470 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373028084; called by muse, mutect2
- PLCE1 | c.2842C>T p.H948Y | Missense Mutation (SNP) | VAF 194/307 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs757606247; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCL1 | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 85/317 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs752227939; called by muse, mutect2, varscan2
- PLCL2 | c.2312G>A p.G771E (on ENST00000615277 / NM_001144382.2; = p.G645E on NM_015184.5) | Missense Mutation (SNP) | VAF 167/186 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67621935; called by muse, mutect2, varscan2
- PLK1 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 217/439 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.199); catalogued as rs1274670002, COSV100267418; called by muse, mutect2, varscan2
- PLXNA2 | c.3665C>T p.S1222L | Missense Mutation (SNP) | VAF 197/304 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs866518301; called by muse, mutect2, varscan2
- PM20D1 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 165/253 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as COSV65648551; called by muse, mutect2, varscan2
- PPP6C | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 147/248 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV65206937; called by muse, mutect2, varscan2
- PREX2 | c.4603C>T p.R1535W | Missense Mutation (SNP) | VAF 137/248 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs139672596, COSV55752095, COSV55765100; called by muse, mutect2, varscan2
- PROKR1 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 92/331 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs540828482; called by muse, mutect2, varscan2
- PSD4 | c.2461G>A p.G821R | Missense Mutation (SNP) | VAF 92/282 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55530936; called by muse, mutect2, varscan2
- PSMA4 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 124/276 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767513513; called by muse, mutect2, varscan2
- PSMC1 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as COSV54321375; called by muse, mutect2, varscan2
- PXDNL | c.4361G>A p.G1454E | Missense Mutation (SNP) | VAF 166/368 reads (45%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs267601939, COSV62491875; called by muse, mutect2
- PXDNL | c.1672C>T p.H558Y | Missense Mutation (SNP) | VAF 190/413 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV62500987; called by muse, mutect2, varscan2
- RAI1 | c.5227C>T p.P1743S | Missense Mutation (SNP) | VAF 133/470 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs776853629; called by muse, mutect2, varscan2
- RAPGEF3 | c.2258C>T p.S753F (on ENST00000389212; = p.S711F on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 309/323 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs764660320; called by muse, mutect2, varscan2
- RAPGEF5 | c.1133G>A p.G378E (on ENST00000401957 / NM_001367602.2; = p.G681E on NM_012294.5) | Missense Mutation (SNP) | VAF 107/324 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.296); catalogued as COSV100687114; called by muse, mutect2, varscan2
- RBM27 | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 88/311 reads (28%) | catalogued as COSV99505791; called by muse, mutect2, varscan2
- REV3L | c.3958C>T p.P1320S | Missense Mutation (SNP) | VAF 178/198 reads (90%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs750607371; called by muse, mutect2, varscan2
- RGS21 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV69882046; called by muse, mutect2, varscan2
- RIOK3 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV59774186; called by muse, mutect2, varscan2
- RIPPLY1 | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 92/101 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1156929034; called by muse, mutect2, varscan2
- ROS1 | c.7039G>A p.D2347N | Missense Mutation (SNP) | VAF 133/157 reads (85%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV63861340; called by muse, mutect2, varscan2
- ROS1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 218/241 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV63854206; called by muse, mutect2, varscan2
- RP1L1 | c.2078G>A p.R693Q | Missense Mutation (SNP) | VAF 291/604 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs201625937; called by muse, mutect2, varscan2
- RTN1 | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 304/488 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV50719063; called by muse, mutect2, varscan2
- SCARB1 | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 396/417 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs766544619, COSV55553821; called by muse, mutect2, varscan2
- SCN10A | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 1423/1700 reads (84%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV71862092; called by muse, mutect2, varscan2
- SCN11A | c.3064G>A p.G1022S | Missense Mutation (SNP) | VAF 132/988 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.271); catalogued as rs144070491; called by muse, mutect2, varscan2
- SCN5A | c.3080G>A p.R1027Q | Missense Mutation (SNP) | VAF 310/2148 reads (14%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.833); catalogued as rs763891399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN7A | c.3353G>A p.W1118* | Nonsense Mutation (SNP) | VAF 75/260 reads (29%) | catalogued as COSV101313323; called by muse, mutect2, varscan2
- SCN7A | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated (1); PolyPhen possibly damaging (0.459); catalogued as rs970770597, COSV69267984; called by muse, mutect2, varscan2
- SDK1 | c.3793G>A p.E1265K | Missense Mutation (SNP) | VAF 101/348 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.054); catalogued as rs200558524; called by muse, mutect2, varscan2
- SEC16B | c.3082C>T p.P1028S | Missense Mutation (SNP) | VAF 182/317 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779566889; called by muse, mutect2, varscan2
- SEMA4F | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 96/317 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs770865563; called by muse, mutect2, varscan2
- SENP5 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 283/305 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.254); catalogued as COSV100052087; called by muse, mutect2, varscan2
- SH3TC1 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 170/508 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755241625, COSV99794782; called by muse, mutect2, varscan2
- SHISA6 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 126/387 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as rs1438215129; called by muse, varscan2
- SHKBP1 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 906/1090 reads (83%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52539089; called by muse, mutect2, varscan2
- SI | c.4618C>T p.H1540Y | Missense Mutation (SNP) | VAF 113/129 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as rs764235215, COSV52265334; called by muse, mutect2, varscan2
- SIX2 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 316/540 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.078); catalogued as rs772787033; called by muse, mutect2, varscan2
- SKOR2 | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious, low confidence (0); catalogued as rs751349792, COSV71111716; called by muse, mutect2, varscan2
- SLC16A3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 168/472 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as rs776036203; called by muse, mutect2, varscan2
- SLC22A12 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 149/495 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as rs759293917, COSV100327843; called by muse, mutect2, varscan2
- SLC39A12 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV66202865; called by muse, mutect2, varscan2
- SLC43A1 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 114/349 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs370138109; called by muse, mutect2, varscan2
- SLC8A3 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 201/360 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63523166; called by muse, mutect2, varscan2
- SLIT1 | c.3844G>A p.E1282K | Missense Mutation (SNP) | VAF 167/270 reads (62%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.508); catalogued as rs774613268, COSV56596755; called by muse, mutect2, varscan2
- SMOC1 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 106/385 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV62759494; called by muse, mutect2, varscan2
- SOWAHB | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 269/441 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV57554536, COSV57554915; called by muse, mutect2, varscan2
- SPATA18 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 96/311 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1207210735, COSV54644107; called by muse, mutect2, varscan2
- SPATA31D1 | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 210/323 reads (65%) | SIFT tolerated (0.6); PolyPhen benign (0.082); catalogued as rs373293574, COSV61201629; called by muse, mutect2, varscan2
- SPATA48 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 111/170 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs575358865; called by muse, mutect2, varscan2
- SPECC1L | c.2653-1G>A p.X885_splice | Splice Site (SNP) | VAF 133/261 reads (51%) | catalogued as COSV100063151; called by muse, mutect2, varscan2
- SPHKAP | c.4625G>A p.R1542Q | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs368367152, COSV60881066; called by muse, mutect2, varscan2
- SPON1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 116/177 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV59970143; called by muse, mutect2, varscan2
- SPTB | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 274/427 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV67633352; called by muse, mutect2, varscan2
- SPZ1 | c.723G>A p.M241I | Missense Mutation (SNP) | VAF 194/309 reads (63%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs759863632; called by muse, mutect2, varscan2
- ST8SIA4 | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 83/141 reads (59%) | PolyPhen benign (0.049); catalogued as COSV99185099; called by muse, mutect2, varscan2
- ST8SIA5 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 94/337 reads (28%) | PolyPhen benign (0.015); catalogued as rs772209308, COSV59330330; called by muse, mutect2, varscan2
- STIP1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 126/396 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs1309804488; called by muse, mutect2, varscan2
- SVEP1 | c.10027G>A p.G3343R | Missense Mutation (SNP) | VAF 96/310 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as rs1239693078; called by muse, mutect2, varscan2
- SVEP1 | c.6698C>T p.P2233L | Missense Mutation (SNP) | VAF 141/223 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs552783679; called by muse, mutect2, varscan2
- SYK | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1028055781; called by muse, mutect2, varscan2
- SYNE1 | c.509G>A p.R170Q (on ENST00000367255 / NM_182961.4; = p.R177Q on NM_033071.3) | Missense Mutation (SNP) | VAF 167/181 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779239788; called by muse, mutect2, varscan2
- TBC1D30 | c.2320C>T p.P774S (on ENST00000542120; = p.P611S on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 461/488 reads (94%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs1565694792, COSV57483084; called by muse, mutect2, varscan2
- TCF20 | c.5789C>T p.P1930L | Missense Mutation (SNP) | VAF 262/610 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV100166400; called by muse, mutect2, varscan2
- TDG | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 153/443 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); catalogued as rs772013454; called by muse, mutect2, varscan2
- TENM4 | c.5328G>A p.M1776I | Missense Mutation (SNP) | VAF 137/450 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV53614270, COSV53662137; called by muse, mutect2, varscan2
- TENM4 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 163/265 reads (62%) | SIFT tolerated (0.79); PolyPhen benign (0.085); catalogued as rs754421992, COSV99574075; called by muse, mutect2, varscan2
- THSD7B | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 127/201 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV55654590; called by muse, mutect2, varscan2
- TIE1 | c.1607C>T p.T536I | Missense Mutation (SNP) | VAF 212/232 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs763117481; called by muse, mutect2, varscan2
- TIMD4 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 101/333 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as rs758058713, COSV50856101; called by muse, mutect2, varscan2
- TMPRSS3 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 259/502 reads (52%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.955); catalogued as COSV52300375; called by muse, mutect2, varscan2
- TMPRSS7 | c.2390G>A p.R797Q (on ENST00000452346; = p.R671Q on NM_001042575.2) | Missense Mutation (SNP) | VAF 131/140 reads (94%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as rs778513781, COSV69981663; called by muse, mutect2, varscan2
- TNFRSF11B | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 116/269 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV99816997; called by muse, mutect2, varscan2
- TNNI3 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 137/488 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as rs587782980, CM1411050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNR | c.3521G>A p.G1174E | Missense Mutation (SNP) | VAF 164/252 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV54915860; called by muse, mutect2, varscan2
- TNRC18 | c.7958C>T p.S2653F | Missense Mutation (SNP) | VAF 342/600 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs757833275, COSV99064193; called by muse, varscan2
- TP53BP2 | c.2138C>A p.S713Y (on ENST00000343537 / NM_001031685.3; = p.S584Y on NM_005426.2) | Missense Mutation (SNP) | VAF 196/349 reads (56%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs189590424, COSV100636497, COSV59066985; called by muse, mutect2, varscan2
- TRANK1 | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 246/1794 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1393575235; called by muse, mutect2, varscan2
- TRAV8-3 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 86/308 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as rs1169383871; called by muse, mutect2
- TRBV20OR9-2 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 263/277 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1276388123; called by muse, mutect2, varscan2
- TRHDE | c.2746G>A p.D916N | Missense Mutation (SNP) | VAF 278/301 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs770407748, COSV53858679; called by muse, mutect2, varscan2
- TRIM55 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 238/524 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52543080; called by muse, mutect2, varscan2
- TRPM8 | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 133/425 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs201939575, COSV61221390; called by muse, mutect2, varscan2
- TSBP1 | c.266G>A p.R89Q (on ENST00000617061; = p.R113Q on NM_006781.5) | Missense Mutation (SNP) | VAF 129/142 reads (91%) | SIFT tolerated (0.99); PolyPhen benign (0.053); catalogued as rs765734658, COSV66660353, COSV99055748; called by muse, mutect2, varscan2
- TSC1 | c.2815G>A p.G939R | Missense Mutation (SNP) | VAF 76/259 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs1564471685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSHZ2 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 268/531 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.368); catalogued as COSV61591408; called by muse, mutect2, varscan2
- TSPAN15 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 112/318 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100960368; called by muse, mutect2, varscan2
- TSPOAP1 | c.3193G>A p.E1065K | Missense Mutation (SNP) | VAF 182/544 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1292237649; called by muse, mutect2, varscan2
- TTC29 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as COSV100284479; called by muse, mutect2, varscan2
- TTC6 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 188/288 reads (65%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as rs1395484872; called by muse, mutect2, varscan2
- TTC6 | c.1412A>G p.E471G (on ENST00000267368; = p.E1837G on NM_001310135.3) | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs1362855162; called by muse, mutect2, varscan2
- TTN | c.99682G>A p.E33228K (on ENST00000591111; = p.E25804K on NM_003319.4) | Missense Mutation (SNP) | VAF 137/423 reads (32%) | PolyPhen benign (0.197); catalogued as rs563430855, COSV59874413; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.50773G>A p.E16925K (on ENST00000591111; = p.E9501K on NM_003319.4) | Missense Mutation (SNP) | VAF 174/308 reads (56%) | PolyPhen benign (0.229); catalogued as COSV59889003; called by muse, mutect2, varscan2
- TUBA3C | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 141/341 reads (41%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.017); catalogued as COSV67139711; called by muse, mutect2, varscan2
- TUFT1 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 173/301 reads (57%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as rs1470411735; called by muse, mutect2, varscan2
- TUT4 | c.3016C>T p.R1006C | Missense Mutation (SNP) | VAF 183/202 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57118968; called by muse, mutect2, varscan2
- UBE3A | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 163/346 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV51662589; called by muse, mutect2, varscan2
- UNC13C | c.5984G>A p.G1995D | Missense Mutation (SNP) | VAF 94/230 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs975096476; called by muse, mutect2, varscan2
- UTP20 | c.3650C>T p.P1217L | Missense Mutation (SNP) | VAF 213/220 reads (97%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV99882228; called by muse, mutect2, varscan2
- VANGL2 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766369773, COSV63604847; called by muse, mutect2, varscan2
- VCAN | c.5071C>T p.P1691S | Missense Mutation (SNP) | VAF 95/333 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1383037859; called by muse, mutect2, varscan2
- WDR25 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 237/381 reads (62%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs753716361, COSV100092188; called by muse, mutect2, varscan2
- WDR33 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 99/357 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.276); catalogued as COSV100459696; called by muse, mutect2, varscan2
- WDR72 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 112/285 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1354323534; called by muse, mutect2
- WDR81 | c.3725C>T p.S1242F (on ENST00000409644 / NM_001163809.2; = p.S191F on NM_152348.4) | Missense Mutation (SNP) | VAF 129/452 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58489186; called by muse, mutect2, varscan2
- WDR87 | c.4241G>A p.G1414E | Missense Mutation (SNP) | VAF 191/1440 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.083); catalogued as COSV58193729; called by muse, mutect2, varscan2
- WDR87 | c.3745C>T p.L1249F | Missense Mutation (SNP) | VAF 118/1826 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772266230; called by muse, mutect2
- WFS1 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 272/426 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1423902367; called by muse, mutect2, varscan2
- WNT5A | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 68/75 reads (91%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs369165725; called by muse, mutect2, varscan2
- XDH | c.3581G>A p.G1194E | Missense Mutation (SNP) | VAF 144/224 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1388492434, COSV65151695; called by muse, mutect2, varscan2
- ZC3H13 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 122/284 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.968); catalogued as rs1387828464; called by muse, varscan2
- ZEB2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 86/256 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV57955896; called by muse, mutect2, varscan2
- ZER1 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 79/331 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771809504; called by muse, mutect2, varscan2
- ZNF208 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 240/1485 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV68102775; called by muse, varscan2
- ZNF33B | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 87/293 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63943451; called by muse, mutect2, varscan2
- ZNF595 | c.54G>A p.W18* | Nonsense Mutation (SNP) | VAF 41/762 reads (5%) | catalogued as rs865999328, COSV100227741, COSV59548346; called by muse, mutect2
- ZNF649 | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 153/611 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV56813878; called by muse, mutect2, varscan2
- ZNF671 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 119/631 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100235344, COSV58053298; called by muse, mutect2, varscan2
- ZNF729 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 597/812 reads (74%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs536246557; called by muse, mutect2, varscan2
- ZNF831 | c.2575G>A p.D859N | Missense Mutation (SNP) | VAF 280/578 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV100926125; called by muse, varscan2
- ZNF862 | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 302/328 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778873772; called by muse, varscan2
- ZSCAN1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 198/987 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs774632461, COSV56605431; called by muse, mutect2, varscan2
- ABAT | c.957T>C p.H319= | Splice Region (SNP) | VAF 113/277 reads (41%) | called by muse, mutect2, varscan2
- ABCC8 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 112/426 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- AC090517.4 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACE | c.2530G>A p.E844K | Missense Mutation (SNP) | VAF 129/396 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ADAM29 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 264/374 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADAMTS2 | c.1754C>T p.T585I | Missense Mutation (SNP) | VAF 97/299 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADPRHL1 | c.5501G>A p.R1834K | Missense Mutation (SNP) | VAF 126/285 reads (44%) | SIFT tolerated, low confidence (0.15); called by muse, mutect2, varscan2
- ADRA2C | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 133/427 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGBL1 | c.2840A>G p.K947R | Missense Mutation (SNP) | VAF 130/304 reads (43%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- AJM1 | c.812C>G p.P271R | Missense Mutation (SNP) | VAF 264/431 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ALMS1 | c.11026A>G p.K3676E | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ALX3 | c.145A>G p.T49A | Missense Mutation (SNP) | VAF 398/430 reads (93%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMER3 | c.473A>C p.K158T | Missense Mutation (SNP) | VAF 241/396 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANAPC1 | c.3736C>T p.P1246S | Missense Mutation (SNP) | VAF 84/331 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- ANKRD12 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ANKRD12 | c.2150C>A p.S717Y | Missense Mutation (SNP) | VAF 75/123 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ANKRD50 | c.3395C>G p.T1132R | Missense Mutation (SNP) | VAF 96/352 reads (27%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ANTXR1 | c.1398T>G p.D466E | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ANXA8 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- APAF1 | c.2549C>T p.P850L (on ENST00000551964 / NM_181861.2; = p.P839L on NM_013229.3) | Missense Mutation (SNP) | VAF 240/259 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- APBB1IP | c.1155G>A p.K385= | Splice Region (SNP) | VAF 96/157 reads (61%) | called by muse, mutect2, varscan2
- APOL5 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 293/593 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARHGAP17 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 172/397 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ARID3B | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 144/383 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ASIC5 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 223/378 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ATP10A | c.3772C>T p.P1258S | Missense Mutation (SNP) | VAF 214/490 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- ATP12A | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 111/266 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP1B2 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- AXDND1 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 153/237 reads (65%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- C10orf71 | c.2756C>T p.P919L | Missense Mutation (SNP) | VAF 120/403 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- C12orf75 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 171/189 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- C2CD2 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 252/553 reads (46%) | SIFT tolerated (0.88); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- C3 | c.2744C>T p.A915V | Missense Mutation (SNP) | VAF 88/201 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, varscan2
- C5orf47 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 77/128 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CACNA1A | c.6094G>A p.E2032K | Missense Mutation (SNP) | VAF 200/213 reads (94%) | SIFT tolerated (0.08); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- CACNA1S | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.469); called by muse, varscan2
- CAMSAP2 | c.2431C>T p.P811S (on ENST00000236925 / NM_001297707.2; = p.P800S on NM_203459.3) | Missense Mutation (SNP) | VAF 186/299 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CAPG | c.518A>G p.N173S | Missense Mutation (SNP) | VAF 166/278 reads (60%) | SIFT tolerated (0.63); PolyPhen benign (0.005); called by muse, mutect2
- CCDC144A | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 126/410 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- CCL1 | c.210A>T p.K70N | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD1C | c.146G>A p.W49* | Nonsense Mutation (SNP) | VAF 239/414 reads (58%) | called by muse, mutect2, varscan2
- CDH4 | c.2636C>T p.S879F | Missense Mutation (SNP) | VAF 304/638 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEACAM3 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 122/1558 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2
- CFAP47 | c.3035G>A p.G1012E | Missense Mutation (SNP) | VAF 94/100 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CFAP54 | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 154/167 reads (92%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHTF8 | c.284T>A p.L95Q | Missense Mutation (SNP) | VAF 117/490 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CIC | c.2140G>A p.G714R | Missense Mutation (SNP) | VAF 138/2344 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- CKAP5 | c.5704G>A p.G1902S (on ENST00000529230 / NM_001008938.4; = p.G1842S on NM_014756.3) | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CLEC4F | c.1538A>T p.Q513L | Missense Mutation (SNP) | VAF 101/296 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CNGA3 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 252/393 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNOT6L | c.1655C>T p.P552L (on ENST00000504123 / NM_001286790.2; = p.P547L on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL4A1 | c.3508C>T p.L1170= | Splice Region (SNP) | VAF 97/197 reads (49%) | called by muse, mutect2, varscan2
- COL4A3 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 100/186 reads (54%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- COL4A3 | c.2554C>T p.P852S | Missense Mutation (SNP) | VAF 191/305 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- COL4A3 | c.4081G>A p.G1361R | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A6 | c.4037G>A p.G1346E | Missense Mutation (SNP) | VAF 148/164 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 134/248 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CP | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 99/113 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CPSF1 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 221/472 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CRB1 | c.4182G>A p.W1394* | Nonsense Mutation (SNP) | VAF 171/269 reads (64%) | called by muse, mutect2, varscan2
- CRYBG1 | c.4370G>A p.W1457* | Nonsense Mutation (SNP) | VAF 150/165 reads (91%) | called by muse, mutect2, varscan2
- CSMD1 | c.4916C>T p.S1639L (on ENST00000520002; = p.S1638L on NM_033225.6) | Missense Mutation (SNP) | VAF 133/280 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CSMD3 | c.6172C>T p.P2058S (on ENST00000297405 / NM_001363185.1; = p.P1954S on NM_052900.3) | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CSN2 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CTNND2 | c.2199G>T p.M733I | Missense Mutation (SNP) | VAF 127/359 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CUX2 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 324/357 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- DACT2 | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 157/338 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DIAPH1 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 162/260 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- DIO3 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 178/510 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DKK4 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 249/526 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DMBT1 | c.7376G>A p.G2459E (on ENST00000338354 / NM_001377530.1; = p.G1702E on NM_004406.3) | Missense Mutation (SNP) | VAF 82/283 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMD | c.2566C>T p.Q856* | Nonsense Mutation (SNP) | VAF 188/194 reads (97%) | called by muse, mutect2, varscan2
- DNAAF1 | c.880T>C p.W294R | Missense Mutation (SNP) | VAF 154/337 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH17 | c.10822G>A p.G3608R | Missense Mutation (SNP) | VAF 208/308 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH5 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 91/161 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DNM1 | c.2067G>A p.M689I | Missense Mutation (SNP) | VAF 174/256 reads (68%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- DOCK1 | c.5543C>T p.P1848L | Missense Mutation (SNP) | VAF 175/276 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DOCK3 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 211/233 reads (91%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- DSG4 | c.2027G>A p.G676E | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DUOX1 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 207/467 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DUSP2 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 132/447 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EP400 | c.8042C>T p.T2681I | Missense Mutation (SNP) | VAF 392/405 reads (97%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ERBB4 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERN2 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 175/403 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ETS1 | c.1276_1278delinsTC p.P426Sfs*120 | Frame Shift Del (DEL) | VAF 196/532 reads (37%) | called by pindel, varscan2*
- FAM120C | c.1144T>G p.F382V | Missense Mutation (SNP) | VAF 126/128 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM153B | c.571G>A p.E191K (on ENST00000253490; = p.E114K on NM_001265615.1) | Missense Mutation (SNP) | VAF 92/668 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FAM169A | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 56/204 reads (27%) | called by muse, mutect2, varscan2
- FAM216A | c.81G>A p.W27* | Nonsense Mutation (SNP) | VAF 400/429 reads (93%) | called by muse, mutect2, varscan2
- FILIP1L | c.1696G>A p.D566N (on ENST00000354552 / NM_182909.3; = p.D326N on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 201/219 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- FMN2 | c.2878C>T p.P960S | Missense Mutation (SNP) | VAF 85/346 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.941); called by muse, varscan2
- FMO5 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 93/161 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FOXI1 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 119/439 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GAS2 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 160/257 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GFPT2 | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 128/230 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GLRB | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- GNGT2 | c.182A>C p.K61T | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGA8S | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by mutect2, varscan2
- GPR75 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 226/363 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- GRID2 | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 145/258 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GRIK1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 220/456 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- GRM7 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 75/89 reads (84%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GRPR | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 166/175 reads (95%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTF3C3 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 125/232 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HEATR5A | c.5684_5724del p.Y1895Sfs*10 | Frame Shift Del (DEL) | VAF 132/290 reads (46%) | called by mutect2, pindel, varscan2
- HERC2 | c.9586C>T p.P3196S | Missense Mutation (SNP) | VAF 322/708 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEYL | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 359/392 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- HGD | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 204/226 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- HK3 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 191/348 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLA-DRA | c.579G>A p.W193* | Nonsense Mutation (SNP) | VAF 313/344 reads (91%) | called by muse, mutect2, varscan2
- HYDIN | c.12962G>A p.G4321E | Missense Mutation (SNP) | VAF 104/319 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HYDIN | c.11791C>T p.P3931S | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- HYDIN | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 120/306 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IBSP | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 156/466 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.027); called by muse, mutect2
- IGHE | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF9 | c.2929C>T p.P977S (on ENST00000368094 / NM_001135050.2; = p.P961S on NM_020789.4) | Missense Mutation (SNP) | VAF 146/495 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IL1RAPL2 | c.987T>A p.Y329* | Nonsense Mutation (SNP) | VAF 124/136 reads (91%) | called by muse, mutect2, varscan2
- IL4 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 203/335 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- INHA | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 115/419 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQCN | c.3320C>T p.P1107L | Missense Mutation (SNP) | VAF 278/628 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IRAG2 | c.3830C>T p.S1277F (on ENST00000636465; = p.S322F on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/315 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IRS2 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 136/337 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, varscan2
- ITGA7 | c.2939C>T p.P980L (on ENST00000555728; = p.P936L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 230/243 reads (95%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- ITIH6 | c.3562G>A p.E1188K | Missense Mutation (SNP) | VAF 155/353 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- JAKMIP1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 394/600 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2
- JAKMIP2 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 173/263 reads (66%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- KCNN2 | c.1627C>T p.Q543* (on ENST00000264773; = p.Q755* on NM_021614.4) | Nonsense Mutation (SNP) | VAF 282/458 reads (62%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1786G>A p.G596S (on ENST00000359125 / NM_172107.4; = p.G568S on NM_004518.6) | Missense Mutation (SNP) | VAF 180/356 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- KHDC1 | c.557A>T p.N186I (on ENST00000370384 / NM_001251874.2; = p.N113I on NM_030568.5) | Missense Mutation (SNP) | VAF 209/227 reads (92%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- KIAA0232 | c.2924T>A p.F975Y | Missense Mutation (SNP) | VAF 251/393 reads (64%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- KIF17 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 257/283 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- KIF18A | c.2411C>T p.S804L | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- KIF21B | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF27 | c.1813C>T p.H605Y | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLF18 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 177/186 reads (95%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- KLF4 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 266/420 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KMT2C | c.13181C>T p.P4394L | Missense Mutation (SNP) | VAF 312/329 reads (95%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRT12 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 334/541 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KRT14 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 187/360 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- KRT33A | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 214/320 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KRTAP10-6 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 102/278 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- L1TD1 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 225/246 reads (91%) | SIFT tolerated (0.83); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- LAMB1 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 411/430 reads (96%) | called by muse, mutect2, varscan2
- LILRA2 | c.71-1G>T p.X24_splice | Splice Site (SNP) | VAF 182/509 reads (36%) | called by muse, mutect2, varscan2
- LILRB1 | c.1015C>T p.L339F (on ENST00000427581; = p.L303F on NM_006669.6) | Missense Mutation (SNP) | VAF 304/1442 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- LIX1 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 121/390 reads (31%) | called by muse, mutect2, varscan2
- LMAN1 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 160/259 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- LRIT1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 138/529 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- LRIT3 | c.491G>A p.R164K | Missense Mutation (SNP) | VAF 115/347 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- LRP1B | c.5113G>A p.G1705R | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- LRRC46 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 124/217 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LRRIQ1 | c.3935T>C p.I1312T | Missense Mutation (SNP) | VAF 240/260 reads (92%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LTBP4 | c.3362G>A p.S1121N (on ENST00000308370 / NM_001042544.1; = p.S1084N on NM_003573.2) | Missense Mutation (SNP) | VAF 150/2010 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.902); called by muse, mutect2
- LYST | c.8869C>T p.R2957* | Nonsense Mutation (SNP) | VAF 182/299 reads (61%) | called by muse, mutect2, varscan2
- M6PR | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 322/582 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARCHF8 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 117/413 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAST4 | c.5752C>T p.P1918S (on ENST00000403625 / NM_001164664.2; = p.P1729S on NM_015183.3) | Missense Mutation (SNP) | VAF 119/394 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MEFV | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 125/280 reads (45%) | called by muse, mutect2, varscan2
- MMP25 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 278/545 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MPP6 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 144/223 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MRGPRX2 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 99/321 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- MSR1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 113/218 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MUC16 | c.38083G>A p.G12695S | Missense Mutation (SNP) | VAF 109/119 reads (92%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- MUC16 | c.16313C>T p.S5438F | Missense Mutation (SNP) | VAF 256/279 reads (92%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC17 | c.11824C>T p.P3942S | Missense Mutation (SNP) | VAF 328/349 reads (94%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- MUC5AC | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 200/323 reads (62%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- MYH8 | c.4075G>A p.E1359K | Missense Mutation (SNP) | VAF 120/423 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO5B | c.1916C>T p.S639F | Missense Mutation (SNP) | VAF 136/230 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYO5B | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 173/251 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MYOZ2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MYPN | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 222/355 reads (63%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NAALADL1 | c.1508G>A p.S503N | Missense Mutation (SNP) | VAF 170/296 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NACAD | c.4543G>A p.E1515K | Missense Mutation (SNP) | VAF 81/289 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- NAT2 | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 183/400 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- NBEA | c.2337G>A p.K779= | Splice Region (SNP) | VAF 56/142 reads (39%) | called by muse, mutect2, varscan2
- NCAN | c.2854C>T p.P952S | Missense Mutation (SNP) | VAF 327/646 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- NCAPH2 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 268/577 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- NCR3 | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 279/307 reads (91%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEB | c.4257G>A p.M1419I | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NEURL1B | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 176/549 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEURL3 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 80/311 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- NLRC3 | c.2588C>T p.T863I | Missense Mutation (SNP) | VAF 232/455 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- NOS1 | c.4016C>T p.S1339F | Missense Mutation (SNP) | VAF 274/294 reads (93%) | SIFT tolerated (0.08); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- NR2F1 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 205/324 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRP1 | c.2719G>C p.V907L | Missense Mutation (SNP) | VAF 95/359 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NSMCE4A | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 78/318 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- NWD1 | c.3512G>A p.G1171E | Missense Mutation (SNP) | VAF 271/577 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- NYNRIN | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 118/388 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.13976G>A p.G4659E | Missense Mutation (SNP) | VAF 144/524 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- OLFM2 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 255/268 reads (95%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- OR12D1 | c.32T>A p.L11H | Missense Mutation (SNP) | VAF 184/191 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR52A1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 107/354 reads (30%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- OR5B21 | c.897G>A p.W299* | Nonsense Mutation (SNP) | VAF 65/214 reads (30%) | called by muse, mutect2, varscan2
- OR8D2 | c.587A>C p.E196A | Missense Mutation (SNP) | VAF 117/314 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PAK5 | c.266T>C p.F89S | Missense Mutation (SNP) | VAF 203/397 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PALLD | c.2825G>A p.G942E (on ENST00000505667 / NM_001166108.2; = p.G925E on NM_016081.4) | Missense Mutation (SNP) | VAF 96/291 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- PCDH9 | c.1732C>T p.Q578* | Nonsense Mutation (SNP) | VAF 92/204 reads (45%) | called by muse, mutect2, varscan2
- PCNX1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 224/361 reads (62%) | SIFT tolerated (0.51); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PHOX2B | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 275/452 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- PIEZO1 | c.2767T>C p.F923L | Missense Mutation (SNP) | VAF 198/463 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PKD1L2 | c.255G>A p.W85* | Nonsense Mutation (SNP) | VAF 156/317 reads (49%) | called by muse, mutect2, varscan2
- PKMYT1 | c.981T>C p.G327= | Splice Region (SNP) | VAF 227/457 reads (50%) | called by muse, mutect2, varscan2
- PLXNB2 | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 249/550 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- POU2F2 | c.1370T>A p.I457N (on ENST00000526816 / NM_001207025.3; = p.I441N on NM_002698.5) | Missense Mutation (SNP) | VAF 1150/1372 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); called by mutect2, varscan2
- PPRC1 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 102/388 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- PRDM10 | c.1883T>A p.F628Y | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRKCQ | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRRC2C | c.2111C>T p.S704L (on ENST00000367742; = p.S702L on NM_015172.4) | Missense Mutation (SNP) | VAF 233/360 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- PRSS45P | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 264/286 reads (92%) | SIFT tolerated (0.48); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRSS56 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN20 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 98/376 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN21 | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPN5 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 133/220 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PZP | c.4002G>A p.M1334I | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RAET1G | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 341/384 reads (89%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- RASGRF1 | c.1667A>G p.D556G | Missense Mutation (SNP) | VAF 203/476 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- RASSF6 | c.162G>A p.R54= (on ENST00000342081 / NM_201431.2; = p.R22= on NM_177532.5) | Splice Region (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- RBFOX1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 236/506 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.023); called by muse, varscan2
- RBM11 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 196/405 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBMS1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- RBP3 | c.2750C>T p.T917I | Missense Mutation (SNP) | VAF 141/517 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RC3H1 | c.3349G>T p.G1117W | Missense Mutation (SNP) | VAF 225/334 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RC3H2 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- RCSD1 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 270/415 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- REC114 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 161/347 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- REV3L | c.2965A>T p.N989Y | Missense Mutation (SNP) | VAF 87/94 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RIMS1 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 150/163 reads (92%) | SIFT tolerated (0.06); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- ROBO3 | c.3670G>A p.A1224T | Missense Mutation (SNP) | VAF 143/426 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ROCK1 | c.1622C>A p.S541Y | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- RP1 | c.3796G>A p.E1266K | Missense Mutation (SNP) | VAF 139/330 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPTN | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 142/486 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2
- RTL3 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 418/438 reads (95%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SAMD15 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 137/466 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2
- SAMD9 | c.3574T>C p.Y1192H | Missense Mutation (SNP) | VAF 270/291 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SBK3 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 255/787 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SCAPER | c.1457T>G p.M486R | Missense Mutation (SNP) | VAF 165/335 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- SCN9A | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 163/276 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERTAD4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 241/383 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERTM1 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 89/222 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SETD5 | c.3854C>T p.P1285L | Missense Mutation (SNP) | VAF 225/249 reads (90%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGK2 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 202/431 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SH2D3C | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 189/310 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SH3RF2 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 140/438 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SHE | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 161/244 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIX2 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 313/540 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SLC44A5 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 150/171 reads (88%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SLC52A1 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 135/402 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9A4 | c.2237G>A p.R746K | Missense Mutation (SNP) | VAF 91/336 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK1 | c.11G>A p.W4* | Nonsense Mutation (SNP) | VAF 48/133 reads (36%) | called by muse, mutect2, varscan2
- SP140 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 102/338 reads (30%) | called by muse, mutect2, varscan2
- SPANXN4 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 107/119 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SPEM3 | c.1384C>T p.H462Y | Missense Mutation (SNP) | VAF 94/356 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- SPTBN1 | c.1966G>T p.E656* | Nonsense Mutation (SNP) | VAF 149/415 reads (36%) | called by muse, mutect2, varscan2
- SPTLC3 | c.450G>A p.W150* | Nonsense Mutation (SNP) | VAF 149/307 reads (49%) | called by muse, mutect2, varscan2
- SRCIN1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 263/413 reads (64%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SRPX2 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 88/99 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRSF12 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 213/237 reads (90%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SSRP1 | c.1315G>C p.D439H | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SULT1C4 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 111/201 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SVEP1 | c.3062G>A p.G1021E | Missense Mutation (SNP) | VAF 197/343 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNJ1 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 143/324 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYS1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 151/346 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SYT1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 181/196 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF1L | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 270/288 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- TERB2 | c.658A>G p.K220E | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TEX13C | c.1578G>A p.M526I | Missense Mutation (SNP) | VAF 151/166 reads (91%) | SIFT tolerated (0.07); called by muse, mutect2, varscan2
- TGM6 | c.1376A>G p.N459S | Missense Mutation (SNP) | VAF 190/474 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- TK2 | c.77C>T p.P26L (on ENST00000299697; = p.P82L on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 202/399 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM266 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 245/501 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMOD2 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 117/263 reads (44%) | SIFT tolerated (0.81); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TMPRSS4 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 222/390 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- TNFRSF11A | c.784-1G>A p.X262_splice | Splice Site (SNP) | VAF 120/207 reads (58%) | called by muse, mutect2, varscan2
- TNK2 | c.2321C>T p.S774F | Missense Mutation (SNP) | VAF 292/321 reads (91%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- TNN | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 185/306 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TPTE | c.1147C>A p.Q383K (on ENST00000618007 / NM_199261.4; = p.Q365K on NM_199259.4) | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, varscan2
- TPTE2 | c.472dup p.Y158Lfs*5 | Frame Shift Ins (INS) | VAF 24/64 reads (38%) | called by pindel, varscan2
- TRANK1 | c.8689G>A p.E2897K | Missense Mutation (SNP) | VAF 78/655 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRARG1 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 330/511 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TRPC6 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 110/332 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- TTC30A | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 121/421 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TTC37 | c.3703T>C p.Y1235H | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- TTN | c.51445G>A p.G17149R (on ENST00000591111; = p.G9725R on NM_003319.4) | Missense Mutation (SNP) | VAF 81/241 reads (34%) | PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- UGP2 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 237/345 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UGT2B11 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 86/300 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- UNC13D | c.684G>A p.R228= | Splice Region (SNP) | VAF 85/295 reads (29%) | called by muse, mutect2, varscan2
- USH2A | c.4523C>T p.S1508F | Missense Mutation (SNP) | VAF 194/335 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- USP17L7 | c.1425G>A p.M475I | Missense Mutation (SNP) | VAF 289/648 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- VCPKMT | c.439T>A p.Y147N | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VSTM1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 224/1069 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- VWA2 | c.1543G>A p.G515R | Missense Mutation (SNP) | VAF 90/303 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWA5B1 | c.2969-1G>A p.X990_splice (on ENST00000375079; = p.X985_splice on NM_001039500.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 157/176 reads (89%) | called by muse, mutect2, varscan2
- WASHC2A | c.1228T>G p.S410A | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- WWC2 | c.2741T>G p.V914G | Missense Mutation (SNP) | VAF 134/429 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- XDH | c.1434G>A p.W478* | Nonsense Mutation (SNP) | VAF 156/257 reads (61%) | called by muse, mutect2, varscan2
- ZBTB1 | c.1577del p.L526Yfs*23 | Frame Shift Del (DEL) | VAF 162/356 reads (46%) | called by mutect2, pindel, varscan2
- ZC3H11B | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 115/225 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.069); called by muse, mutect2
- ZDBF2 | c.2660C>T p.P887L | Missense Mutation (SNP) | VAF 92/247 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- ZFPM2 | c.1105C>T p.H369Y | Missense Mutation (SNP) | VAF 204/472 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZG16 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 145/386 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF229 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 172/190 reads (91%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF471 | c.257-1G>C p.X86_splice | Splice Site (SNP) | VAF 98/778 reads (13%) | called by muse, mutect2, varscan2
- ZNF536 | c.2903C>T p.S968F | Missense Mutation (SNP) | VAF 770/1024 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZNF580 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 298/875 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ZNF615 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 157/711 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZNF624 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 90/276 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZNF639 | c.636_657del p.N212Kfs*5 | Frame Shift Del (DEL) | VAF 172/206 reads (83%) | called by mutect2, pindel, varscan2
- ZNF804A | c.2627G>A p.R876K | Missense Mutation (SNP) | VAF 108/354 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF831 | c.4747G>A p.E1583K | Missense Mutation (SNP) | VAF 193/414 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ZNF85 | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 162/175 reads (93%) | SIFT tolerated (0.3); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ZNF850 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 261/585 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZSCAN2 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 260/556 reads (47%) | called by muse, mutect2, varscan2
- ZZEF1 | c.7429C>T p.P2477S | Missense Mutation (SNP) | VAF 117/347 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- AARD | c.402G>A p.K134= | Silent (SNP) | VAF 154/392 reads (39%) | catalogued as rs1189028493; called by muse, mutect2, varscan2
- AASDH | c.1491C>T p.I497= | Silent (SNP) | VAF 94/334 reads (28%) | called by muse, mutect2
- ABCA7 | c.3891C>T p.L1297= | Silent (SNP) | VAF 215/238 reads (90%) | catalogued as rs368024653; called by muse, mutect2, varscan2
- ABCC1 | c.1422C>T p.V474= | Silent (SNP) | VAF 291/563 reads (52%) | called by muse, mutect2, varscan2
- AC100868.1 | c.1851C>T p.S617= | Silent (SNP) | VAF 250/535 reads (47%) | called by muse, mutect2, varscan2
- ACP4 | c.1269G>A p.G423= | Silent (SNP) | VAF 173/209 reads (83%) | catalogued as rs772566181; called by muse, mutect2, varscan2
- ADAM19 | c.720C>T p.I240= | Silent (SNP) | VAF 103/182 reads (57%) | catalogued as rs1487407223; called by muse, mutect2, varscan2
- ADAM29 | c.1809G>A p.E603= | Silent (SNP) | VAF 228/378 reads (60%) | catalogued as rs764914357; called by muse, mutect2, varscan2
- ADAMTS16 | c.132T>C p.R44= | Silent (SNP) | VAF 112/398 reads (28%) | catalogued as rs760357771; called by muse, mutect2, varscan2
- ADAMTS8 | c.2436G>A p.V812= | Silent (SNP) | VAF 249/439 reads (57%) | called by muse, mutect2, varscan2
- ADGRB2 | c.2433C>T p.S811= | Silent (SNP) | VAF 329/360 reads (91%) | called by muse, mutect2, varscan2
- ADGRG4 | c.4920C>T p.I1640= | Silent (SNP) | VAF 101/111 reads (91%) | catalogued as COSV54963920; called by muse, mutect2, varscan2
- ADGRV1 | c.10653G>A p.V3551= | Silent (SNP) | VAF 64/290 reads (22%) | catalogued as rs1426116692; called by muse, mutect2, varscan2
- AGER | c.255C>T p.F85= | Silent (SNP) | VAF 353/387 reads (91%) | called by muse, mutect2, varscan2
- AKAP17A | c.447C>T p.I149= | Silent (SNP) | VAF 413/891 reads (46%) | called by muse, mutect2, varscan2
- ALDH8A1 | c.802C>T p.L268= | Silent (SNP) | VAF 131/310 reads (42%) | catalogued as rs1349566413; called by muse, mutect2, varscan2
- ALK | c.3522C>T p.F1174= | Silent (SNP) | VAF 61/197 reads (31%) | catalogued as COSV66555460, COSV66556325; called by muse, mutect2, varscan2
- ALK | c.2757G>A p.G919= | Silent (SNP) | VAF 56/167 reads (34%) | catalogued as rs1309115542, COSV66571597; called by muse, mutect2, varscan2
- ALOX5 | c.1962G>A p.K654= | Silent (SNP) | VAF 155/512 reads (30%) | called by muse, mutect2, varscan2
- ANKRD30A | c.543G>A p.T181= (on ENST00000611781; = p.T125= on NM_052997.2) | Silent (SNP) | VAF 60/189 reads (32%) | catalogued as rs748801395, COSV64609214, COSV64609913; called by muse, mutect2, varscan2
- ANO4 | c.567C>T p.I189= (on ENST00000392977 / NM_001286615.2; = p.I154= on NM_178826.4) | Silent (SNP) | VAF 238/249 reads (96%) | catalogued as rs1346144989, COSV100152626, COSV54587272; called by muse, mutect2, varscan2
- AOC1 | c.2145C>T p.I715= | Silent (SNP) | VAF 436/458 reads (95%) | catalogued as rs758756420, COSV62869128, COSV62871309; called by muse, mutect2, varscan2
- AP1AR | c.375C>T p.L125= | Silent (SNP) | VAF 57/229 reads (25%) | catalogued as COSV56770663; called by muse, mutect2, varscan2
- AQR | c.3861C>T p.V1287= | Silent (SNP) | VAF 104/241 reads (43%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.3783C>T p.I1261= | Silent (SNP) | VAF 156/177 reads (88%) | catalogued as COSV68335137; called by muse, mutect2, varscan2
- ARNT | c.2358C>T p.P786= | Silent (SNP) | VAF 67/259 reads (26%) | called by muse, mutect2, varscan2
- ASPRV1 | c.831G>A p.A277= | Silent (SNP) | VAF 227/351 reads (65%) | catalogued as rs139581474; called by muse, mutect2, varscan2
- ATF4 | c.717G>A p.R239= | Silent (SNP) | VAF 107/456 reads (23%) | called by muse, mutect2, varscan2
- ATOH1 | c.252C>T p.S84= | Silent (SNP) | VAF 149/530 reads (28%) | catalogued as rs745854214, COSV60037851; called by muse, mutect2, varscan2
- ATP13A1 | c.1293C>T p.L431= | Silent (SNP) | VAF 143/1282 reads (11%) | catalogued as rs772971611; called by muse, mutect2, varscan2
- ATP8B2 | c.258C>T p.F86= (on ENST00000672630; = p.F53= on NM_001005855.2) | Silent (SNP) | VAF 193/323 reads (60%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.1341G>A p.L447= | Silent (SNP) | VAF 244/423 reads (58%) | catalogued as rs1279910458; called by muse, mutect2, varscan2
- BCR | c.3372C>T p.I1124= | Silent (SNP) | VAF 118/396 reads (30%) | catalogued as rs774751445; called by muse, mutect2, varscan2
- BMP7 | c.618G>A p.S206= | Silent (SNP) | VAF 124/269 reads (46%) | catalogued as rs779335170, COSV67779880, COSV67780030; called by muse, mutect2, varscan2
- BNC1 | c.579C>T p.I193= | Silent (SNP) | VAF 197/456 reads (43%) | catalogued as COSV61757582; called by muse, mutect2, varscan2
- BPIFB6 | c.1065C>T p.L355= | Silent (SNP) | VAF 142/316 reads (45%) | called by muse, mutect2, varscan2
- BRSK2 | c.1323C>T p.L441= | Silent (SNP) | VAF 278/450 reads (62%) | catalogued as rs764422459; called by muse, mutect2, varscan2
- C10orf105 | c.15C>T p.G5= | Silent (SNP) | VAF 112/335 reads (33%) | called by muse, mutect2, varscan2
- C2CD4A | c.540C>T p.R180= | Silent (SNP) | VAF 205/523 reads (39%) | called by muse, mutect2, varscan2
- C7orf25 | c.1182C>T p.I394= | Silent (SNP) | VAF 237/365 reads (65%) | catalogued as rs781296015, COSV100623668; called by muse, mutect2, varscan2
- CACNA1C | c.1929C>T p.S643= | Silent (SNP) | VAF 209/530 reads (39%) | called by muse, mutect2, varscan2
- CACNA1S | c.1719C>T p.F573= | Silent (SNP) | VAF 214/322 reads (66%) | catalogued as rs759501199, COSV62938377; ClinVar: likely benign; called by muse, varscan2
- CAPN13 | c.1422C>T p.F474= | Silent (SNP) | VAF 172/290 reads (59%) | called by muse, mutect2, varscan2
- CAVIN4 | c.201C>T p.S67= | Silent (SNP) | VAF 126/403 reads (31%) | catalogued as rs574438701; called by muse, mutect2, varscan2
- CCDC102B | c.1005C>T p.S335= | Silent (SNP) | VAF 90/152 reads (59%) | called by muse, mutect2, varscan2
- CCDC158 | c.2988C>T p.F996= | Silent (SNP) | VAF 130/227 reads (57%) | called by muse, mutect2, varscan2
- CCDC168 | c.7593C>T p.F2531= | Silent (SNP) | VAF 92/212 reads (43%) | called by muse, mutect2, varscan2
- CCDC33 | c.810C>T p.F270= | Silent (SNP) | VAF 204/429 reads (48%) | catalogued as rs1479233724, COSV58352244; called by muse, mutect2, varscan2
- CCDC54 | c.381C>T p.L127= | Silent (SNP) | VAF 163/178 reads (92%) | catalogued as rs1174221802, COSV53757938; called by muse, mutect2, varscan2
368 further variants in this file (0 protein-altering or splice-affecting, 333 silent, 35 other) are not listed here.
